Surgical pathology report (de-identified scan), TCGA case TCGA-34-5929, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-5929-01A (Primary Tumor).

[page 1 of 2]
PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS:
PROCEDURE: Bronchoscopy / mediastinoscopy / left VATS.
SPECIFIC CLINICAL QUESTION: Not answered.
OUTSIDE TISSUE DIAGNOSIS: Not answered.
PRIOR MALIGNANCY: Not answered.
CHEMORADIATION THERAPY: Not answered.
ORGAN TRANSPLANT: Not answered.
IMMUNOSUPPRESSION: Not answered.
OTHER DISEASES: Not answered.
CYTOGENETICS TESTING: Not answered.

FINAL DIAGNOSIS:**SUMMARY STATEMENT**

The left upper lobe demonstrates a 4.8 cm poorly differentiated squamous cell carcinoma associated with angiolymphatic invasion. No evidence of visceral pleural invasion. All sampled lymph nodes are benign. Surgical resection margins are benign. Pathologic stage: T2aN0Mx.

**PART 1: LYMPH NODE, SUBCARINAL, BIOPSY –
THREE (3) FRAGMENTS OF BENIGN LYMPH NODE.**

**PART 2: LYMPH NODE, RIGHT TRACHEAL BRONCHIAL ANGLE, BIOPSY –
THREE (3) FRAGMENTS OF BENIGN LYMPH NODE.**

**PART 3: LYMPH NODE, LEFT TRACHEAL BRONCHIAL, BIOPSY –
TWO (2) FRAGMENTS OF BENIGN LYMPH NODE.**

**PART 4: LYMPH NODE, SUBINNOMINATE, BIOPSY –
TWO (2) FRAGMENTS OF BENIGN LYMPH NODE.**

**PART 5: LYMPH NODE, RIGHT PARATRACHEAL, BIOPSY –
ONE (1) BENIGN LYMPH NODE.**

**PART 6: LYMPH NODE, LEFT UPPER LOBE, BIOPSY –
ONE (1) BENIGN LYMPH NODE.**

**PART 7: LYMPH NODE, LEFT UPPER LOBE BRONCHUS, BIOPSY –
TWO (2) FRAGMENTS OF BENIGN LYMPH NODE.**

PART 8: LUNG, LEFT UPPER LOBE, LOBECTOMY –

- A. POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (4.8 CM IN DIAMETER) ASSOCIATED WITH ANGIOLYMPHATIC INVASION. NO EVIDENCE OF VISCERAL PLEURAL INVASION. MILD LYMPHOCYTIC HOST RESPONSE. TWO (2) FRAGMENTS OF BENIGN LYMPH N1 LYMPH NODES. PATHOLOGIC STAGE: T2aN0Mx.**
- B. BRONCHIAL RESECTION MARGIN WITH FOCAL SQUAMOUS METAPLASIA BUT NO EVIDENCE OF DYSPLASIA OR CARCINOMA. VASCULAR RESECTION MARGIN IS BENIGN.**
- C. BACKGROUND LUNG WITH RESPIRATORY BRONCHIOLITIS AND EMPHYSEMATOUS CHANGE.**

**PART 9: LYMPH NODE, AP WINDOW, BIOPSY –
ONE (1) BENIGN LYMPH NODE.**

**PART 10: LYMPH NODE, SUBCARINAL, BIOPSY –
ONE (1) BENIGN LYMPH NODE.**

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY LUNG TUMORS**

TUMOR LOCATION:	Left Upper Lobe
PROCEDURE:	Lobectomy
TUMOR SIZE:	Maximum dimension: 4.8 cm Minor dimension: 4.1 cm
GROSS SATELLITES:	Number of gross satellite lesions: 0
TUMOR TYPE:	Invasive squamous carcinoma, peripheral type
HISTOLOGIC GRADE:	G3, Poorly differentiated
MICROSCOPIC "SATELLITES"/METASTASES:	Number of microscopic lesions: 0
EXTRAPULMONARY EXTENSION/INVASION OF TUMOR:	None identified (PLO)
ANGIOLYMPHATIC INVASION:	Yes
TUMOR NECROSIS:	> 50%
SURGICAL MARGIN INVOLVEMENT:	No
SURGICAL MARGIN SITE:	Distance of invasive tumor to closest margin: 2 mm
INFLAMMATORY(DESMOPLASTIC) REACTION:	Mild
N1 LYMPH NODES:	Number of N1 lymph nodes positive: 0 Number of N1 lymph nodes examined: 5
N2 LYMPH NODES:	Number of N2 lymph nodes positive: 0 Number of N2 lymph nodes examined: 13
UNDERLYING DISEASE(S):	Emphysema, Smokers bronchiolitis
T STAGE, PATHOLOGIC:	pT2a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	Not applicable
ANCILLARY STUDIES:	Histochemical stains, Immunohistochemical stains, FISH studies

[page 2 of 2]
ADDENDA:

Addendum

PROBE: LSI *EGFR*/CEP7 Dual-Color Probe

***EGFR* FISH STUDIES PERFORMED ON THE SQUAMOUS CELL CARCINOMA ARE NEGATIVE BY**

Number of cells analyzed: 60

Ratio *EGFR*/CEP7: 1.09

SNR (signal to nucleus ratio): 1.9

Hyperdiploid rate for CEP 7: 0%

~~>4 copies of the *EGFR* signal: 2(3.3%)~~

Small gene cluster (4-10 copies): 0(0%)

Larger and brighter *EGFR* signals than CEP7 signals: 3(5.0%)

>15 copies of *EGFR* signals: 0(0%)

PROBE: LSI *ALK* Dual-Color Break-apart Probe 2p23

***ALK* FISH STUDIES PERFORMED ON THE SQUAMOUS CELL CARCINOMA ARE NEGATIVE.**

Number of cells analyzed: 61

% of cells positive for the *ALK* rearrangement: 1(1.6%)

Only split O & G (single O and single G in the same nucleus: 0%

Fusion + split O and G in the same nucleus: 0%

Only single O: 0%

Fusion + single O: 1(1.6%)

% of the cells with the normal pattern: 60(98.4%)

UCCC criteria for stratification of NSCLC patients:

***EGFR* FISH positive:**

1) *EGFR* gene amplification defined as one of the following:

- a) ~~*EGFR* gene to CEP7 ratio ≥ 2~~
- b) Small gene cluster (4-10 copies) or innumerable tight gene cluster in $> 10\%$ of tumor cells
- c) Larger and brighter *EGFR* signals than CEP7 signals in $> 10\%$ of tumor cells, while *EGFR* signals are smaller than the CEP7 signals in the adjacent stromal and reactive cells
- d) > 15 copies of the *EGFR* signals in $> 10\%$ of tumor cells **or**
- 2) Specimens with $\geq 40\%$ of cells displaying ≥ 4 copies of the *EGFR* signal.

***EGFR* FISH negative:**

Specimens without gene amplification as defined above and with $\leq 40\%$ of cells displaying ≥ 4 copies of the *EGFR* signal.

Clinical studies show high *EGFR* gene copy number by FISH analysis to be associated with favorable clinical benefit (clinical response, stable disease, time to progression, and survival) in patients with advanced non-small cell lung cancer treated with *EGFR* tyrosine kinase inhibitors.

Source: NCI Genomic Data Commons file 7574b6a6-980e-425d-a856-5423464c39d8 (TCGA-34-5929.9FCFE85F-C7ED-4C1F-B21A-DAE956CF8616.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).